Somatic mutation profile of tumor specimen C3N-05624-03 (aliquot CPT0322650006) from CPTAC case C3N-05624, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIID; Age at diagnosis: 72.1 years (26,328 days).
Specimen C3N-05624-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 787763a2-d6a1-48e6-a091-89eee7c9a2aa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-05624-31 (Blood Derived Normal), aliquot CPT0322690002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4fc8fddb-be1c-481d-b13b-f840d443376e

The open-access MAF lists 968 somatic variants for this specimen: 615 protein-altering or splice-affecting, 316 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 558, Silent 316, Nonsense Mutation 39, Intron 24, Splice Region 6, Splice Site 5, Frame Shift Del 4, 3'UTR 4, RNA 3, 5'UTR 2, 5'Flank 2, Translation Start Site 2.

Variants (750 of 968; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 204/433 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- TP53 | c.839G>T p.R280I | Missense Mutation (SNP) | VAF 157/469 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AACS | c.553C>A p.P185T | Missense Mutation (SNP) | VAF 113/403 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as COSV55536359; called by muse, mutect2, varscan2
- AADACL4 | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 69/531 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs1180730720, COSV66106814; called by muse, mutect2, varscan2
- ABCA13 | c.13292G>A p.G4431E | Missense Mutation (SNP) | VAF 58/366 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68946394; called by muse, mutect2, varscan2
- ABCC3 | c.3503G>T p.R1168L | Missense Mutation (SNP) | VAF 140/616 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.209); catalogued as COSV53326200; called by muse, mutect2, varscan2
- ABCF2 | c.713C>T p.A238V | Missense Mutation (SNP) | VAF 44/598 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs754716865; called by muse, mutect2
- ACP6 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 43/375 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.691); catalogued as COSV65077465; called by muse, mutect2, varscan2
- ACSM4 | c.1361G>A p.G454E | Missense Mutation (SNP) | VAF 233/625 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101257140; called by muse, mutect2, varscan2
- ACSM5 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 112/475 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); catalogued as rs1567340745, COSV59370368, COSV59370530; called by muse, mutect2, varscan2
- ADAM7 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 37/325 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs1333012683, COSV51535711; called by muse, mutect2, varscan2
- ADAMTSL1 | c.101G>A p.G34D | Missense Mutation (SNP) | VAF 132/459 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV52818812; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4294C>T p.H1432Y | Missense Mutation (SNP) | VAF 110/366 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs868539604, COSV65878545; called by muse, mutect2, varscan2
- ADGRB2 | c.3265C>T p.L1089= | Splice Region (SNP) | VAF 137/526 reads (26%) | catalogued as rs1187285192; called by muse, mutect2, varscan2
- ADGRE1 | c.95-1G>A p.X32_splice | Splice Site (SNP) | VAF 86/340 reads (25%) | catalogued as rs1177784868; called by muse, mutect2, varscan2
- ADH1B | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 33/341 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.471); catalogued as rs770117532, COSV59295307; called by muse, mutect2, varscan2
- ADRA1D | c.1358C>T p.S453L | Missense Mutation (SNP) | VAF 68/534 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1039273133; called by muse, mutect2, varscan2
- AGMO | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); catalogued as rs1273447604, COSV61105744; called by muse, mutect2, varscan2
- AHNAK2 | c.1331C>T p.P444L | Missense Mutation (SNP) | VAF 178/553 reads (32%) | SIFT tolerated (0.77); PolyPhen benign (0.039); catalogued as COSV100318965, COSV60911105; called by muse, mutect2, varscan2
- ALDH1A3 | c.742C>T p.P248S | Missense Mutation (SNP) | VAF 95/480 reads (20%) | SIFT tolerated (0.84); PolyPhen benign (0.061); catalogued as rs1007040444; called by muse, mutect2, varscan2
- ALDH9A1 | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 127/490 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV61339719; called by muse, mutect2, varscan2
- AMZ1 | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 56/287 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.109); catalogued as rs766281461, COSV56687453; called by muse, mutect2, varscan2
- ANK3 | c.9494G>A p.S3165N | Missense Mutation (SNP) | VAF 62/470 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.227); catalogued as COSV99782920; called by muse, mutect2, varscan2
- ANK3 | c.6853G>A p.D2285N | Missense Mutation (SNP) | VAF 71/490 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV55064792; called by muse, mutect2, varscan2
- ANKRD62 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 121/331 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1299911588, COSV100018873; called by muse, mutect2, varscan2
- APCS | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 61/461 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99661194; called by muse, mutect2, varscan2
- APOB | c.12457C>T p.Q4153* | Nonsense Mutation (SNP) | VAF 106/493 reads (22%) | catalogued as rs1228367728; called by muse, mutect2, varscan2
- ARHGAP32 | c.5357G>A p.G1786E (on ENST00000310343 / NM_001378025.1; = p.G1437E on NM_014715.4) | Missense Mutation (SNP) | VAF 159/693 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as rs1363690409; called by muse, mutect2, varscan2
- ARID2 | c.1624C>T p.R542* | Nonsense Mutation (SNP) | VAF 87/243 reads (36%) | catalogued as COSV57595668; called by muse, mutect2, varscan2
- ASAH2 | c.998G>A p.G333E | Missense Mutation (SNP) | VAF 88/352 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.678); catalogued as rs1269772733; called by muse, mutect2, varscan2
- ASPM | c.5842C>T p.R1948C | Missense Mutation (SNP) | VAF 59/557 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.225); catalogued as rs375852743; called by muse, mutect2, varscan2
- ATAD3C | c.310G>A p.G104R | Missense Mutation (SNP) | VAF 185/664 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV66481834; called by muse, mutect2, varscan2
- ATP10A | c.3587C>T p.S1196L | Missense Mutation (SNP) | VAF 51/373 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as rs1193674809; called by muse, mutect2, varscan2
- ATP1B4 | c.365C>T p.S122F (on ENST00000218008 / NM_001142447.3; = p.S118F on NM_012069.5) | Missense Mutation (SNP) | VAF 126/226 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs372328601; called by muse, mutect2, varscan2
- ATP8B4 | c.1235G>T p.R412I | Missense Mutation (SNP) | VAF 79/366 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.035); catalogued as COSV52726883; called by muse, mutect2, varscan2
- B4GALT2 | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 53/445 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751764862; called by muse, mutect2, varscan2
- BCL9L | c.392C>T p.S131F | Missense Mutation (SNP) | VAF 120/449 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.687); catalogued as rs927232835; called by muse, mutect2, varscan2
- BCO1 | c.1060C>T p.P354S | Missense Mutation (SNP) | VAF 137/618 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV50734463; called by muse, mutect2, varscan2
- BEND4 | c.1243C>T p.L415F | Missense Mutation (SNP) | VAF 89/520 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV72469402; called by muse, mutect2, varscan2
- C16orf96 | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 160/608 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.253); catalogued as rs1277387366, COSV101474583; called by muse, mutect2, varscan2
- C2orf78 | c.2119C>T p.H707Y | Missense Mutation (SNP) | VAF 138/642 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.182); catalogued as rs563561388; called by muse, mutect2, varscan2
- CACHD1 | c.3517G>A p.E1173K | Missense Mutation (SNP) | VAF 135/509 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.935); catalogued as rs748338922; called by muse, mutect2, varscan2
- CACNA1I | c.1801G>A p.A601T | Missense Mutation (SNP) | VAF 278/668 reads (42%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1343815526; called by muse, mutect2, varscan2
- CALML3 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 166/619 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.473); catalogued as rs1234491898, COSV59449329, COSV59450362; called by muse, mutect2, varscan2
- CAPN6 | c.254C>T p.S85F | Missense Mutation (SNP) | VAF 70/241 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV60693723; called by muse, mutect2, varscan2
- CASP12 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 109/482 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); catalogued as rs892949449, COSV65259603; called by muse, mutect2, varscan2
- CAVIN2 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 140/684 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.215); catalogued as COSV58424217; called by muse, varscan2
- CCDC40 | c.2104G>A p.V702M | Missense Mutation (SNP) | VAF 141/600 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.079); catalogued as rs748948064; called by muse, mutect2, varscan2
- CD79B | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 154/645 reads (24%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV50075959, COSV50076941; called by muse, mutect2, varscan2
- CDH13 | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 93/455 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1477620126, COSV99227440; called by muse, mutect2, varscan2
- CDSN | c.1568G>A p.G523E | Missense Mutation (SNP) | VAF 104/599 reads (17%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.039); catalogued as rs565620030, COSV52539896; called by muse, mutect2, varscan2
- CFAP46 | c.2375G>A p.R792Q | Missense Mutation (SNP) | VAF 141/458 reads (31%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.998); catalogued as rs957189721, COSV63951047; called by muse, mutect2, varscan2
- CHD5 | c.2683C>T p.P895S | Missense Mutation (SNP) | VAF 91/324 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as rs1467019165; called by muse, mutect2, varscan2
- CHMP7 | c.776C>T p.S259F | Missense Mutation (SNP) | VAF 41/357 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV57534104; called by muse, mutect2, varscan2
- CHST4 | c.616G>T p.D206Y | Missense Mutation (SNP) | VAF 163/705 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58297088; called by muse, mutect2, varscan2
- CILP2 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 117/456 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV52273156; called by muse, mutect2, varscan2
- CLCA4 | c.2278G>A p.D760N | Missense Mutation (SNP) | VAF 51/586 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1188303649, COSV65282050; called by muse, mutect2
- CLEC7A | c.635C>T p.T212I (on ENST00000304084 / NM_197947.3; = p.T166I on NM_022570.5) | Missense Mutation (SNP) | VAF 114/584 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as COSV53721176; called by muse, mutect2, varscan2
- COL12A1 | c.2501G>A p.W834* | Nonsense Mutation (SNP) | VAF 100/525 reads (19%) | catalogued as rs758060047; called by muse, mutect2, varscan2
- COL15A1 | c.2299G>A p.G767R | Missense Mutation (SNP) | VAF 71/277 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66642864, COSV66646208; called by muse, mutect2, varscan2
- COL28A1 | c.1702C>T p.P568S | Missense Mutation (SNP) | VAF 61/410 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.245); catalogued as COSV101258553; called by muse, mutect2, varscan2
- COL4A5 | c.169G>A p.G57R | Missense Mutation (SNP) | VAF 78/213 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1490099715; called by muse, mutect2, varscan2
- COL4A5 | c.170G>A p.G57E | Missense Mutation (SNP) | VAF 78/212 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60368028; called by muse, mutect2, varscan2
- CPAMD8 | c.2947C>T p.P983S (on ENST00000651564; = p.P936S on NM_015692.5) | Missense Mutation (SNP) | VAF 125/397 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.121); catalogued as rs1309500474, COSV101488560; called by muse, mutect2, varscan2
- CPLX2 | c.43G>A p.D15N | Missense Mutation (SNP) | VAF 97/382 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV64000593; called by muse, mutect2, varscan2
- CSMD1 | c.5429G>A p.R1810Q (on ENST00000520002; = p.R1809Q on NM_033225.6) | Missense Mutation (SNP) | VAF 81/336 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs770980133, COSV59315770; called by muse, mutect2, varscan2
- CTAGE8 | c.2201G>A p.R734Q | Missense Mutation (SNP) | VAF 39/912 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as rs1203825832; called by muse, mutect2
- CTNNA2 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 110/499 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.029); catalogued as rs766350655, COSV63546883; called by muse, mutect2, varscan2
- CUBN | c.25C>T p.L9F | Missense Mutation (SNP) | VAF 90/333 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.019); catalogued as COSV100910574, COSV64701484; called by muse, mutect2, varscan2
- CYP2A13 | c.619G>A p.G207R | Missense Mutation (SNP) | VAF 74/412 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.03); catalogued as COSV100386689; called by muse, mutect2, varscan2
- CYP2S1 | c.485G>A p.G162E | Missense Mutation (SNP) | VAF 50/367 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV59507286; called by muse, mutect2, varscan2
- DHRS12 | c.748G>A p.D250N (on ENST00000444610 / NM_001377930.1; = p.D201N on NM_024705.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 185/554 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV54470501; called by muse, mutect2, varscan2
- DISP3 | c.2026G>A p.E676K | Missense Mutation (SNP) | VAF 103/419 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.317); catalogued as rs776975033, COSV53829600; called by muse, mutect2, varscan2
- DLGAP3 | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 162/629 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.115); catalogued as COSV99332113; called by muse, mutect2, varscan2
- DMXL2 | c.8971C>T p.R2991* | Nonsense Mutation (SNP) | VAF 166/681 reads (24%) | catalogued as rs775750727, COSV51840432; called by muse, mutect2, varscan2
- DNAJC6 | c.2293G>A p.E765K | Missense Mutation (SNP) | VAF 123/432 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs752833276; called by muse, mutect2, varscan2
- DPRX | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 52/360 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs761892759, COSV64949245; called by muse, mutect2, varscan2
- DSG3 | c.2825C>T p.S942F | Missense Mutation (SNP) | VAF 121/385 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs141527621, COSV57126777; called by muse, mutect2, varscan2
- DSP | c.1879C>T p.P627S | Missense Mutation (SNP) | VAF 141/498 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1446804590; called by muse, mutect2, varscan2
- DUSP10 | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 146/493 reads (30%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs774613067; called by muse, mutect2, varscan2
- ECPAS | c.5092C>T p.P1698S | Missense Mutation (SNP) | VAF 128/386 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV52191232; called by muse, mutect2, varscan2
- EDDM3B | c.102G>A p.M34I | Missense Mutation (SNP) | VAF 103/443 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.677); catalogued as rs865919869, COSV58746693; called by muse, mutect2, varscan2
- EGFR | c.2563G>A p.D855N | Missense Mutation (SNP) | VAF 64/430 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51837705; called by muse, mutect2, varscan2
- EHD3 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 88/432 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770304508, COSV59030441; called by muse, mutect2, varscan2
- ENPEP | c.2449G>A p.E817K | Missense Mutation (SNP) | VAF 91/349 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.441); catalogued as COSV54450303; called by muse, varscan2
- EPB42 | c.269G>A p.W90* (on ENST00000441366 / NM_001114134.2; = p.W120* on NM_000119.3) | Nonsense Mutation (SNP) | VAF 156/612 reads (25%) | catalogued as rs769194025; called by muse, mutect2, varscan2
- ERBB4 | c.3502G>A p.E1168K | Missense Mutation (SNP) | VAF 72/351 reads (21%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.985); catalogued as COSV61463515, COSV61480189; called by muse, mutect2, varscan2
- ERC2 | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 157/619 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.248); catalogued as COSV99888203; called by muse, mutect2, varscan2
- ERICH6 | c.551C>T p.S184L | Missense Mutation (SNP) | VAF 58/323 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs752029105; called by muse, mutect2, varscan2
- ETV3L | c.241G>A p.G81S | Missense Mutation (SNP) | VAF 123/486 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71901017; called by muse, mutect2, varscan2
- EVPL | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 189/786 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758618187, COSV56917091; called by muse, mutect2, varscan2
- F13A1 | c.121A>C p.N41H | Missense Mutation (SNP) | VAF 56/441 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs757568910; called by muse, mutect2, varscan2
- FAM170B | c.415C>T p.H139Y | Missense Mutation (SNP) | VAF 150/595 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV61253893; called by muse, mutect2, varscan2
- FAM184A | c.2287G>A p.E763K | Missense Mutation (SNP) | VAF 93/314 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.566); catalogued as COSV58854308; called by muse, mutect2, varscan2
- FAM221A | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 64/381 reads (17%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.894); catalogued as rs368536274; called by muse, mutect2, varscan2
- FAM47A | c.1709C>T p.S570L | Missense Mutation (SNP) | VAF 157/342 reads (46%) | SIFT tolerated (0.57); PolyPhen benign (0.073); catalogued as rs1339397781, COSV60497528; called by muse, mutect2, varscan2
- FAM83B | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 124/465 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.536); catalogued as rs866283097; called by muse, mutect2, varscan2
- FANCM | c.3913C>T p.P1305S | Missense Mutation (SNP) | VAF 95/406 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.023); catalogued as rs752859049, COSV57498167; called by muse, mutect2, varscan2
- FAT4 | c.13789G>A p.E4597K | Missense Mutation (SNP) | VAF 63/580 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs1347852459, COSV58689889; called by muse, mutect2, varscan2
- FGFR2 | c.2122C>T p.P708S | Missense Mutation (SNP) | VAF 125/514 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60644612; called by muse, mutect2, varscan2
- FIBCD1 | c.1042G>A p.G348R | Missense Mutation (SNP) | VAF 152/559 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs760182396; called by muse, mutect2, varscan2
- FMN2 | c.4231G>A p.E1411K | Missense Mutation (SNP) | VAF 88/349 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779310703, COSV60422534, COSV60455849; called by muse, mutect2, varscan2
- FOXA2 | c.929C>T p.P310L (on ENST00000377115 / NM_153675.3; = p.P316L on NM_021784.5) | Missense Mutation (SNP) | VAF 59/581 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as rs576889997, COSV65796329; called by muse, mutect2, varscan2
- FREM3 | c.2932G>A p.D978N | Missense Mutation (SNP) | VAF 138/505 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.035); catalogued as rs376535520; called by muse, mutect2, varscan2
- FRMD1 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 93/566 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs751929953; called by muse, mutect2, varscan2
- FSHR | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 135/603 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.17); catalogued as COSV100436480, COSV58620693; called by muse, mutect2, varscan2
- FUCA1 | c.601T>C p.F201L | Missense Mutation (SNP) | VAF 131/505 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.139); catalogued as COSV65699318; called by muse, mutect2, varscan2
- FYN | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 88/464 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV57614547; called by muse, mutect2, varscan2
- G6PC2 | c.462G>C p.W154C | Missense Mutation (SNP) | VAF 90/437 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56373615; called by muse, mutect2, varscan2
- GABRG1 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 26/266 reads (10%) | SIFT tolerated (1); PolyPhen possibly damaging (0.689); catalogued as COSV54951561, COSV54962652; called by muse, mutect2, varscan2
- GBP6 | c.341G>A p.W114* | Nonsense Mutation (SNP) | VAF 81/383 reads (21%) | catalogued as COSV65012268; called by muse, mutect2, varscan2
- GCFC2 | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 176/752 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.005); catalogued as rs764549889, COSV58081513; called by muse, mutect2, varscan2
- GCSAML | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 41/234 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); catalogued as rs867029917, COSV63577504; called by muse, mutect2, varscan2
- GFRA1 | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 83/348 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100815348; called by muse, mutect2, varscan2
- GHDC | c.1015C>T p.L339F | Missense Mutation (SNP) | VAF 183/599 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs756053992, COSV100054897; called by muse, mutect2, varscan2
- GIMAP8 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 103/847 reads (12%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.596); catalogued as COSV56229616; called by muse, mutect2, varscan2
- GINS2 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 118/499 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs760747739; called by muse, mutect2, varscan2
- GKN1 | c.404G>A p.G135E | Missense Mutation (SNP) | VAF 135/522 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV65006700; called by muse, mutect2, varscan2
- GPBP1 | c.1102C>T p.R368W | Missense Mutation (SNP) | VAF 162/500 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); catalogued as rs756730058; called by muse, mutect2, varscan2
- GRIK3 | c.1130G>A p.R377Q | Missense Mutation (SNP) | VAF 66/420 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.278); catalogued as COSV66137792; called by muse, mutect2, varscan2
- GRM4 | c.1318C>T p.P440S | Missense Mutation (SNP) | VAF 93/532 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.686); catalogued as rs763177435; called by muse, mutect2, varscan2
- GRM5 | c.1106G>A p.G369E | Missense Mutation (SNP) | VAF 103/402 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CM138106, COSV59605781, COSV59628660; called by muse, mutect2, varscan2
- GRM7 | c.1441C>T p.Q481* | Nonsense Mutation (SNP) | VAF 107/510 reads (21%) | catalogued as COSV63143424; called by muse, mutect2, varscan2
- GTPBP1 | c.1868C>T p.S623F | Missense Mutation (SNP) | VAF 159/632 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.039); catalogued as rs748545641; called by muse, mutect2, varscan2
- HECTD4 | c.13210C>T p.R4404C | Missense Mutation (SNP) | VAF 128/407 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs961224502, COSV66387072; called by muse, mutect2, varscan2
- HELB | c.1616C>T p.P539L | Missense Mutation (SNP) | VAF 93/348 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56072580; called by muse, mutect2, varscan2
- HERC1 | c.2599C>T p.L867F | Missense Mutation (SNP) | VAF 93/404 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV101496543; called by muse, mutect2, varscan2
- HHIPL2 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 60/478 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs766318020; called by muse, mutect2, varscan2
- HRNR | c.7013C>T p.S2338F | Missense Mutation (SNP) | VAF 152/2742 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1433053846; called by muse, mutect2
- HSF1 | c.196A>G p.M66V | Missense Mutation (SNP) | VAF 137/477 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs782246057; called by muse, mutect2, varscan2
- HTR3A | c.220-1G>A p.X74_splice | Splice Site (SNP) | VAF 99/503 reads (20%) | catalogued as rs1381002800, COSV55471080; called by muse, mutect2, varscan2
- HTRA4 | c.1381C>T p.R461W | Missense Mutation (SNP) | VAF 49/445 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); catalogued as rs761178510; called by muse, mutect2, varscan2
- IGFN1 | c.3151G>A p.E1051K (on ENST00000295591 / NM_001367841.1; = p.E3508K on NM_001164586.2) | Missense Mutation (SNP) | VAF 65/536 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as rs746455884, COSV99040862; called by muse, mutect2, varscan2
- IL12RB2 | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 36/261 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374006496, COSV52026731; called by muse, mutect2, varscan2
- IL1R1 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 76/334 reads (23%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as COSV52104992, COSV52106938; called by muse, mutect2, varscan2
- INKA1 | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 227/843 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780619687; called by muse, mutect2, varscan2
- JHY | c.1313C>A p.T438N | Missense Mutation (SNP) | VAF 114/600 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as COSV57075017; called by muse, mutect2, varscan2
- KCND2 | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 52/559 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV58577018; called by muse, mutect2, varscan2
- KCNJ14 | c.1306C>T p.P436S | Missense Mutation (SNP) | VAF 82/289 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as rs1468178337; called by muse, mutect2, varscan2
- KCNQ2 | c.1669G>A p.E557K (on ENST00000359125 / NM_172107.4; = p.E529K on NM_004518.6) | Missense Mutation (SNP) | VAF 116/384 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60553970; called by muse, mutect2, varscan2
- KIAA1755 | c.3280C>T p.P1094S | Missense Mutation (SNP) | VAF 92/616 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.043); catalogued as rs1224522439; called by muse, mutect2, varscan2
- KIF21B | c.1547C>T p.S516F | Missense Mutation (SNP) | VAF 157/614 reads (26%) | SIFT tolerated (0.77); PolyPhen benign (0.241); catalogued as COSV59754638; called by muse, mutect2, varscan2
- KIRREL1 | c.1277G>A p.W426* | Nonsense Mutation (SNP) | VAF 47/354 reads (13%) | catalogued as COSV63290533; called by muse, mutect2, varscan2
- KRT20 | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 188/575 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs755319720; called by muse, mutect2, varscan2
- L1TD1 | c.1547G>A p.G516E | Missense Mutation (SNP) | VAF 134/515 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.023); catalogued as COSV63134301; called by muse, mutect2, varscan2
- L1TD1 | c.2107C>T p.R703C | Missense Mutation (SNP) | VAF 48/423 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs568498567, COSV63133400; called by muse, mutect2, varscan2
- LAMA2 | c.6799G>A p.G2267R | Missense Mutation (SNP) | VAF 102/597 reads (17%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.988); catalogued as rs778379496; called by muse, mutect2, varscan2
- LAMA3 | c.8642C>T p.S2881F (on ENST00000313654 / NM_198129.4; = p.S1272F on NM_000227.6) | Missense Mutation (SNP) | VAF 114/351 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as COSV52530651; called by muse, mutect2, varscan2
- LAMB4 | c.3859G>A p.E1287K | Missense Mutation (SNP) | VAF 60/722 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV52712695; called by muse, mutect2
- LIPE | c.116C>T p.S39L | Missense Mutation (SNP) | VAF 61/483 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs756437778, COSV54921047; called by muse, mutect2, varscan2
- LMO7 | c.4712C>T p.S1571F (on ENST00000357063; = p.S1252F on NM_005358.5) | Missense Mutation (SNP) | VAF 184/541 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.851); catalogued as rs760935363; called by muse, mutect2, varscan2
- LMOD3 | c.1426C>T p.P476S | Missense Mutation (SNP) | VAF 188/686 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as COSV70456147; called by muse, mutect2, varscan2
- LMTK2 | c.4229C>T p.T1410I | Missense Mutation (SNP) | VAF 140/699 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs757663394, COSV52000750; called by muse, mutect2, varscan2
- LPIN1 | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 93/392 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs760516112; called by muse, mutect2, varscan2
- LRFN2 | c.1404G>A p.M468I | Missense Mutation (SNP) | VAF 65/272 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.401); catalogued as rs1413582796, COSV57826925; called by muse, mutect2, varscan2
- LRRTM4 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 122/533 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1301265776; called by muse, mutect2, varscan2
- MAGEL2 | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 145/995 reads (15%) | SIFT deleterious, low confidence (0.05); catalogued as COSV100046135; called by muse, mutect2, varscan2
- MAGI1 | c.2926G>A p.G976R (on ENST00000402939 / NM_001033057.2; = p.G1004R on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 130/634 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.125); catalogued as rs1238360124, COSV100439459, COSV100441451; called by muse, varscan2
- MAN2A2 | c.1885C>T p.R629C | Missense Mutation (SNP) | VAF 116/409 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs748415321; called by muse, mutect2, varscan2
- MATN1 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 56/423 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751495784; called by muse, mutect2, varscan2
- MGAM | c.3318G>A p.W1106* | Nonsense Mutation (SNP) | VAF 241/498 reads (48%) | catalogued as COSV101527702; called by muse, varscan2
- MGAM | c.4003G>A p.V1335M | Missense Mutation (SNP) | VAF 417/878 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.023); catalogued as rs556773642, COSV72073987; called by muse, mutect2, varscan2
- MMP2 | c.1338G>A p.G446= | Splice Region (SNP) | VAF 110/381 reads (29%) | catalogued as rs1283464994; called by muse, mutect2, varscan2
- MMP3 | c.1094G>A p.G365E | Missense Mutation (SNP) | VAF 102/508 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs1555004961, COSV100242966; called by muse, mutect2
- MOSPD2 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 125/295 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.524); catalogued as COSV66860266; called by muse, mutect2, varscan2
- MRPS15 | c.439C>T p.R147* | Nonsense Mutation (SNP) | VAF 122/397 reads (31%) | catalogued as rs940094284; called by muse, mutect2, varscan2
- MUC12 | c.5414C>T p.P1805L (on ENST00000379442; = p.P1662L on NM_001164462.1) | Missense Mutation (SNP) | VAF 126/1024 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV65189702; called by muse, mutect2, varscan2
- MUC16 | c.39221G>A p.G13074E | Missense Mutation (SNP) | VAF 13/309 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.259); catalogued as rs1189611715, COSV66694457; called by muse, mutect2
- MUC16 | c.29483C>T p.S9828F | Missense Mutation (SNP) | VAF 153/453 reads (34%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.155); catalogued as rs1193367378, COSV67472131; called by muse, mutect2, varscan2
- MUSK | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 89/334 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.34); catalogued as COSV51895345; called by muse, mutect2, varscan2
- MYCBP2 | c.8414C>T p.S2805F (on ENST00000357337; = p.S2843F on NM_015057.5) | Missense Mutation (SNP) | VAF 91/352 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.205); catalogued as rs779400903; called by muse, mutect2, varscan2
- MYO1A | c.1790G>A p.R597Q | Missense Mutation (SNP) | VAF 120/396 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs754238164, COSV55655387; called by muse, mutect2, varscan2
- MYOCD | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 48/190 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV100590097; called by mutect2, varscan2
- NFATC1 | c.1900C>T p.P634S | Missense Mutation (SNP) | VAF 87/274 reads (32%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.644); catalogued as rs746612992; called by muse, mutect2, varscan2
- NLRP4 | c.1073G>A p.G358E | Missense Mutation (SNP) | VAF 115/459 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56708963; called by muse, mutect2, varscan2
- NMU | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 110/488 reads (23%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV99946541; called by muse, mutect2, varscan2
- NOS3 | c.2704G>A p.E902K | Missense Mutation (SNP) | VAF 74/758 reads (10%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.858); catalogued as COSV52488621; called by muse, mutect2
- NPY1R | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 73/502 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs772925202, COSV56713356, COSV56713557; called by muse, mutect2, varscan2
- NR5A1 | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 256/765 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.065); catalogued as COSV65295466; called by muse, mutect2, varscan2
- NRCAM | c.268G>A p.D90N (on ENST00000379028 / NM_001371124.1; = p.D84N on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/747 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.129); catalogued as rs766115669, COSV61047405; called by muse, mutect2
- NRG3 | c.1510G>A p.G504R | Missense Mutation (SNP) | VAF 135/517 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.391); catalogued as rs745913146; called by muse, mutect2, varscan2
- NRG3 | c.1511G>A p.G504E | Missense Mutation (SNP) | VAF 135/507 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV64587536; called by muse, mutect2, varscan2
- NUP210L | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 98/367 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.918); catalogued as COSV55155607; called by muse, mutect2, varscan2
- OLR1 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 124/674 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs142675845; called by muse, mutect2, varscan2
- OR10R2 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 95/458 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.763); catalogued as rs553674516, COSV63768532; called by muse, mutect2, varscan2
- OR4D1 | c.509G>A p.G170D | Missense Mutation (SNP) | VAF 145/677 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52126174; called by muse, mutect2, varscan2
- OR4E2 | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 100/443 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1371117158, COSV100330101; called by muse, mutect2, varscan2
- OR4K1 | c.620C>T p.S207L | Missense Mutation (SNP) | VAF 103/755 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV53459364; called by muse, mutect2, varscan2
- OR4M1 | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 121/1234 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as rs749657600, COSV60062051; called by muse, mutect2, varscan2
- OTOF | c.3772G>A p.G1258S | Missense Mutation (SNP) | VAF 106/467 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs1022380480; called by muse, mutect2, varscan2
- P3H2 | c.1283G>A p.G428E | Missense Mutation (SNP) | VAF 67/395 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60022144; called by muse, mutect2, varscan2
- PAPPA2 | c.1532C>T p.S511F | Missense Mutation (SNP) | VAF 117/496 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.035); catalogued as COSV62777306, COSV62784565; called by muse, mutect2, varscan2
- PCDHB6 | c.1683C>A p.Y561* | Nonsense Mutation (SNP) | VAF 166/629 reads (26%) | catalogued as COSV50689925; called by muse, varscan2
- PCDHGA9 | c.2261C>T p.S754F | Missense Mutation (SNP) | VAF 123/393 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as COSV53969127; called by muse, mutect2, varscan2
- PER3 | c.142C>T p.R48* | Nonsense Mutation (SNP) | VAF 57/311 reads (18%) | catalogued as COSV99276343; called by muse, mutect2, varscan2
- PGAP3 | c.332C>T p.S111L | Missense Mutation (SNP) | VAF 168/572 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765176692, COSV100328629; called by muse, mutect2, varscan2
- PKD2L1 | c.1246G>A p.G416R | Missense Mutation (SNP) | VAF 119/522 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.3); catalogued as rs1446026157, COSV100559340, COSV58398828; called by muse, mutect2, varscan2
- PLCE1 | c.5906G>A p.R1969Q | Missense Mutation (SNP) | VAF 46/356 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs1323373118, CM156519, COSV53347495; called by muse, mutect2, varscan2
- PLEKHM2 | c.2303C>A p.P768H | Missense Mutation (SNP) | VAF 164/673 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.227); catalogued as COSV65395604; called by muse, mutect2, varscan2
- PLEKHN1 | c.1888C>T p.P630S (on ENST00000379409; = p.P578S on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 166/589 reads (28%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.009); catalogued as rs1289182988; called by muse, mutect2, varscan2
- POTEB3 | c.409C>T p.R137* | Nonsense Mutation (SNP) | VAF 7/40 reads (18%) | catalogued as rs1220302705; called by mutect2, varscan2
- POU6F2 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 89/490 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.014); catalogued as COSV101302597, COSV68880402; called by muse, mutect2, varscan2
- PP2D1 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 34/484 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as COSV60748011; called by muse, mutect2
- PPARA | c.403G>A p.V135M | Missense Mutation (SNP) | VAF 104/516 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.337); catalogued as rs759527309; called by muse, mutect2, varscan2
- PPRC1 | c.4691C>T p.S1564F | Missense Mutation (SNP) | VAF 114/467 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99531269; called by muse, mutect2, varscan2
- PROSER2 | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 142/533 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.011); catalogued as rs1286071675; called by muse, mutect2, varscan2
- PRR23B | c.362G>A p.G121E | Missense Mutation (SNP) | VAF 84/623 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.726); catalogued as rs1001296311, COSV61494052; called by muse, mutect2, varscan2
- PSD | c.1700G>A p.R567Q | Missense Mutation (SNP) | VAF 85/581 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.046); catalogued as rs1307605002, COSV50041623; called by muse, mutect2, varscan2
- PSG6 | c.1186C>T p.R396C | Missense Mutation (SNP) | VAF 88/669 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs747854367, COSV51831059; called by muse, mutect2, varscan2
- PSG6 | c.708G>A p.P236= | Splice Region (SNP) | VAF 37/283 reads (13%) | catalogued as rs200084592, COSV51832634; called by muse, mutect2, varscan2
- PSKH2 | c.799C>T p.Q267* | Nonsense Mutation (SNP) | VAF 126/447 reads (28%) | catalogued as COSV52612449; called by muse, mutect2, varscan2
- PTCHD3 | c.2167C>T p.P723S | Missense Mutation (SNP) | VAF 101/428 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.024); catalogued as rs748049089, COSV71256817; called by muse, mutect2, varscan2
- PTCHD4 | c.2296T>C p.F766L | Missense Mutation (SNP) | VAF 142/587 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.125); catalogued as COSV100261881; called by muse, mutect2, varscan2
- PTPN13 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 68/444 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765181913; called by muse, mutect2, varscan2
- RASGRP1 | c.1924G>A p.G642S | Missense Mutation (SNP) | VAF 122/548 reads (22%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV60365736; called by muse, mutect2, varscan2
- RBM12 | c.1948C>T p.P650S | Missense Mutation (SNP) | VAF 162/634 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.212); catalogued as rs758887714; called by muse, mutect2, varscan2
- RELN | c.6004G>A p.E2002K | Missense Mutation (SNP) | VAF 109/617 reads (18%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.867); catalogued as rs1370290671, COSV59019457; called by muse, mutect2, varscan2
- RELN | c.2441C>T p.S814L | Missense Mutation (SNP) | VAF 191/399 reads (48%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.942); catalogued as COSV58998145; called by muse, mutect2, varscan2
- RGPD4 | c.1468C>T p.L490F | Missense Mutation (SNP) | VAF 24/496 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.22); catalogued as COSV100736810, COSV61748426; called by muse, mutect2
- RINL | c.643G>A p.G215S (on ENST00000591812 / NM_001195833.2; = p.G101S on NM_198445.4) | Missense Mutation (SNP) | VAF 75/558 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.355); catalogued as rs763988079; called by muse, mutect2, varscan2
- RINT1 | c.310C>T p.R104* | Nonsense Mutation (SNP) | VAF 54/540 reads (10%) | catalogued as rs777242801, COSV57558140; called by muse, mutect2
- RNF165 | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 122/387 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.39); catalogued as rs140779573, COSV99491984; called by muse, mutect2, varscan2
- RNF32 | c.662G>A p.R221K | Missense Mutation (SNP) | VAF 84/506 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as COSV100311564; called by muse, mutect2, varscan2
- RSPH10B | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100521337; called by mutect2, varscan2
- RYR2 | c.13249G>A p.E4417K | Missense Mutation (SNP) | VAF 73/280 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.098); catalogued as COSV63659164; called by muse, mutect2, varscan2
- RYR3 | c.647-1G>A p.X216_splice | Splice Site (SNP) | VAF 67/298 reads (22%) | catalogued as COSV66808027; called by muse, mutect2, varscan2
- RYR3 | c.647G>A p.G216E | Missense Mutation (SNP) | VAF 68/305 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267604156, COSV66796607, COSV66807093; called by muse, mutect2, varscan2
- SALL1 | c.3839G>A p.G1280E | Missense Mutation (SNP) | VAF 125/561 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51764037; called by muse, mutect2, varscan2
- SCIN | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 50/309 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs951090977; called by muse, mutect2, varscan2
- SCN5A | c.1157G>A p.G386E | Missense Mutation (SNP) | VAF 94/464 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199473567, CM100651, COSV61130476; ClinVar: not provided; called by muse, mutect2
- SEC14L5 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 115/544 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.367); catalogued as rs762813191, COSV52041567; called by muse, mutect2, varscan2
- SEMA5A | c.1880C>T p.P627L | Missense Mutation (SNP) | VAF 180/555 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1213167710, COSV101227766, COSV66804328; called by muse, mutect2, varscan2
- SENP3 | c.737C>T p.P246L | Missense Mutation (SNP) | VAF 97/314 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV99547850; called by muse, mutect2, varscan2
- SERPINA3 | c.413G>A p.G138E | Missense Mutation (SNP) | VAF 137/553 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1555386065, COSV67586764; called by muse, mutect2, varscan2
- SETD1A | c.1628C>T p.P543L | Missense Mutation (SNP) | VAF 161/729 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as rs1383171452; called by muse, mutect2, varscan2
- SETD1A | c.5080C>T p.P1694S | Missense Mutation (SNP) | VAF 141/578 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52682112; called by muse, mutect2, varscan2
- SFTPA2 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 52/393 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64882332; called by muse, mutect2, varscan2
- SH3BP1 | c.2065C>T p.P689S | Missense Mutation (SNP) | VAF 126/346 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.42); catalogued as rs780784724; called by mutect2, varscan2
- SLC16A10 | c.1324C>T p.R442C | Missense Mutation (SNP) | VAF 74/307 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs774929205, COSV100920788, COSV64354112; called by muse, mutect2, varscan2
- SLC16A13 | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 159/617 reads (26%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs761677313; called by muse, mutect2, varscan2
- SLC26A3 | c.596G>A p.G199E | Missense Mutation (SNP) | VAF 64/674 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60641518; called by muse, mutect2
- SLC26A7 | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 37/285 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52605955; called by muse, mutect2, varscan2
- SLC2A3 | c.239C>T p.S80F | Missense Mutation (SNP) | VAF 165/804 reads (21%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.99); catalogued as COSV50002948; called by muse, mutect2, varscan2
- SLC4A11 | c.2224G>A p.G742R | Missense Mutation (SNP) | VAF 51/539 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs143965185, CM107638; ClinVar: uncertain significance; called by muse, mutect2
- SLC8A3 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 154/592 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV63519700; called by muse, mutect2, varscan2
- SMAD1 | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 46/307 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.052); catalogued as rs1385105737; called by muse, mutect2, varscan2
- SNAP47 | c.448C>T p.Q150* | Nonsense Mutation (SNP) | VAF 164/609 reads (27%) | catalogued as rs537475220, COSV59918179; called by muse, mutect2, varscan2
- SNCAIP | c.1112C>T p.S371F | Missense Mutation (SNP) | VAF 105/431 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54413018; called by muse, mutect2, varscan2
- SNTN | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 75/520 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs749755057, COSV59538636; called by muse, mutect2, varscan2
- SORCS2 | c.3110G>A p.R1037K | Missense Mutation (SNP) | VAF 92/389 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.012); catalogued as rs1336020468; called by muse, mutect2, varscan2
- SPATA18 | c.1510C>T p.R504* | Nonsense Mutation (SNP) | VAF 32/448 reads (7%) | catalogued as rs778062082, COSV54642305, COSV54650551; called by muse, mutect2
- SPATA31D1 | c.4010C>T p.S1337F | Missense Mutation (SNP) | VAF 128/443 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs967582350, COSV100782971; called by muse, mutect2, varscan2
- SPTBN4 | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 112/626 reads (18%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV58945313; called by muse, mutect2, varscan2
- SPTBN4 | c.1504G>A p.D502N | Missense Mutation (SNP) | VAF 192/695 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs753597803, COSV58946028; called by muse, mutect2, varscan2
- SWI5 | c.34C>T p.R12W | Missense Mutation (SNP) | VAF 247/577 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs1281467692; called by muse, mutect2, varscan2
- SYK | c.1595G>A p.G532E | Missense Mutation (SNP) | VAF 99/327 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65330976; called by muse, mutect2, varscan2
- SYNPO2 | c.1988C>T p.S663L | Missense Mutation (SNP) | VAF 57/553 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV61109264; called by muse, mutect2, varscan2
- TBL3 | c.1201C>T p.R401C | Missense Mutation (SNP) | VAF 121/436 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.091); catalogued as rs367585703; called by muse, mutect2, varscan2
- TDRD5 | c.2221G>A p.D741N | Missense Mutation (SNP) | VAF 78/516 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1181516189, COSV99676806; called by muse, mutect2, varscan2
- TEX13A | c.1172C>T p.S391L | Missense Mutation (SNP) | VAF 126/323 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61146035; called by muse, mutect2, varscan2
- TIAM2 | c.3145G>A p.E1049K | Missense Mutation (SNP) | VAF 57/348 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.165); catalogued as rs1174121781; called by muse, mutect2, varscan2
- TIMD4 | c.131C>T p.S44F | Missense Mutation (SNP) | VAF 133/491 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV50854909; called by muse, mutect2, varscan2
- TMCO3 | c.1451C>T p.P484L | Missense Mutation (SNP) | VAF 125/494 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.912); catalogued as COSV64809003; called by muse, mutect2, varscan2
- TNXB | c.10400C>T p.T3467I (on ENST00000647633; = p.T3220I on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 206/831 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.598); catalogued as COSV64479466; called by muse, mutect2, varscan2
- TPO | c.2200G>A p.E734K | Missense Mutation (SNP) | VAF 100/456 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868428082, COSV104399692, COSV61107691; called by muse, mutect2, varscan2
- TRAF3IP1 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 162/529 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs151259641; called by muse, mutect2, varscan2
- TRIM77 | c.761G>A p.R254K | Missense Mutation (SNP) | VAF 91/440 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.533); catalogued as COSV68066200; called by muse, mutect2, varscan2
- TRIP4 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 124/546 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as rs1265174903; called by muse, mutect2, varscan2
- TRPC4AP | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 81/372 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as COSV52679511; called by muse, mutect2, varscan2
- TTN | c.5011G>A p.E1671K (on ENST00000591111; = p.E1625K on NM_003319.4) | Missense Mutation (SNP) | VAF 161/656 reads (25%) | PolyPhen possibly damaging (0.737); catalogued as COSV60189638; called by muse, mutect2, varscan2
- TTN | c.4852G>A p.D1618N (on ENST00000591111; = p.D1572N on NM_003319.4) | Missense Mutation (SNP) | VAF 84/446 reads (19%) | PolyPhen benign (0.003); catalogued as rs794727465, COSV60065113; called by muse, mutect2, varscan2
- TUBGCP5 | c.1622C>T p.P541L | Missense Mutation (SNP) | VAF 230/848 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1364640382; called by muse, mutect2, varscan2
- UNC13A | c.4526T>G p.I1509S | Missense Mutation (SNP) | VAF 27/576 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV53199011; called by muse, mutect2
- UNC13C | c.1259G>A p.G420E | Missense Mutation (SNP) | VAF 117/537 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.057); catalogued as rs867041374, COSV52840839; called by muse, mutect2, varscan2
- UNC79 | c.4784C>T p.S1595L (on ENST00000393151 / NM_001346218.2; = p.S1418L on NM_020818.5) | Missense Mutation (SNP) | VAF 170/738 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as rs1447169458; called by muse, mutect2
- USP54 | c.4280G>A p.R1427K | Missense Mutation (SNP) | VAF 77/477 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV60449401; called by muse, mutect2, varscan2
- VENTX | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 182/696 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as rs765090857; called by muse, mutect2, varscan2
- VWDE | c.2338C>T p.P780S | Missense Mutation (SNP) | VAF 57/339 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1334284164, COSV51722200; called by muse, mutect2, varscan2
- WNT2 | c.255G>A p.W85* | Nonsense Mutation (SNP) | VAF 139/694 reads (20%) | catalogued as rs1348427387, COSV55411299; called by muse, mutect2, varscan2
- ZAN | c.2087C>T p.P696L | Missense Mutation (SNP) | VAF 111/905 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.159); catalogued as COSV100769686; called by muse, mutect2, varscan2
- ZAN | c.2726C>T p.S909F | Missense Mutation (SNP) | VAF 168/1060 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.281); catalogued as COSV100769461; called by muse, varscan2
- ZC3HC1 | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 43/419 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs750237344; called by muse, mutect2, varscan2
- ZDHHC11 | c.14C>T p.S5F | Missense Mutation (SNP) | VAF 122/411 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as COSV52062818; called by muse, mutect2, varscan2
- ZKSCAN2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 89/334 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs1412399366; called by muse, mutect2, varscan2
- ZNF274 | c.1336C>T p.P446S (on ENST00000610905; = p.P341S on NM_016324.3) | Missense Mutation (SNP) | VAF 62/549 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs531055064; called by muse, mutect2, varscan2
- ZNF334 | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 132/515 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as COSV61619010; called by muse, mutect2, varscan2
- ZNF382 | c.268T>C p.F90L | Missense Mutation (SNP) | VAF 35/274 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV53088174; called by muse, mutect2, varscan2
- ZNF436 | c.424C>T p.H142Y | Missense Mutation (SNP) | VAF 124/442 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs936099841; called by muse, mutect2, varscan2
- ZNF45 | c.1196G>A p.R399Q | Missense Mutation (SNP) | VAF 188/635 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs747087833, COSV54194727; called by muse, mutect2, varscan2
- ZNF827 | c.1104G>T p.E368D | Missense Mutation (SNP) | VAF 44/312 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV101061133; called by muse, mutect2, varscan2
- ZNRF3 | c.1957C>T p.P653S (on ENST00000544604 / NM_001206998.2; = p.P553S on NM_032173.3) | Missense Mutation (SNP) | VAF 121/658 reads (18%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.063); catalogued as rs772125644; called by muse, mutect2, varscan2
- ABCA12 | c.5435G>A p.G1812E (on ENST00000272895 / NM_173076.3; = p.G1494E on NM_015657.3) | Missense Mutation (SNP) | VAF 97/471 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ABCA9 | c.1684G>A p.G562R | Missense Mutation (SNP) | VAF 104/537 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCC6 | c.3886G>A p.G1296S | Missense Mutation (SNP) | VAF 144/590 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCD2 | c.1934G>A p.G645E | Missense Mutation (SNP) | VAF 79/311 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- AC100868.1 | c.1223C>T p.P408L | Missense Mutation (SNP) | VAF 56/427 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ACADL | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 108/487 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ACTBL2 | c.946A>T p.K316* | Nonsense Mutation (SNP) | VAF 166/478 reads (35%) | called by muse, mutect2, varscan2
- ADAM23 | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 129/538 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMDEC1 | c.271C>A p.L91I | Missense Mutation (SNP) | VAF 29/278 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADARB1 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 165/710 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ADCY2 | c.1729C>T p.Q577* | Nonsense Mutation (SNP) | VAF 141/445 reads (32%) | called by muse, mutect2, varscan2
- ADCY5 | c.1726G>A p.G576S | Missense Mutation (SNP) | VAF 127/604 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADCY8 | c.1479C>T p.I493= | Splice Region (SNP) | VAF 89/376 reads (24%) | called by muse, mutect2, varscan2
- ADD3 | c.1468C>T p.Q490* | Nonsense Mutation (SNP) | VAF 52/388 reads (13%) | called by muse, mutect2, varscan2
- ADGRB1 | c.4416G>A p.R1472= | Splice Region (SNP) | VAF 142/529 reads (27%) | called by muse, mutect2, varscan2
- ADGRF4 | c.574C>T p.H192Y | Missense Mutation (SNP) | VAF 83/461 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRF5 | c.2561G>A p.S854N | Missense Mutation (SNP) | VAF 71/385 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- AHCY | c.403C>T p.L135F | Missense Mutation (SNP) | VAF 136/517 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- AKAP8L | c.1475C>T p.P492L | Missense Mutation (SNP) | VAF 25/506 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AKR1C4 | c.356C>A p.P119Q | Missense Mutation (SNP) | VAF 55/371 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AMELY | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 84/222 reads (38%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- ANKRD62 | c.1225G>A p.G409R | Missense Mutation (SNP) | VAF 56/241 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANO1 | c.2836G>A p.E946K | Missense Mutation (SNP) | VAF 151/772 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- ARHGEF10L | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 59/476 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARMC5 | c.2243C>T p.P748L | Missense Mutation (SNP) | VAF 175/733 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- ASPM | c.5033T>A p.L1678Q | Missense Mutation (SNP) | VAF 78/348 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- ASZ1 | c.1423A>C p.K475Q | Missense Mutation (SNP) | VAF 34/336 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.019); called by muse, mutect2
- ATG9A | c.2471C>T p.P824L | Missense Mutation (SNP) | VAF 122/615 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AUTS2 | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 131/656 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- B4GALT2 | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 53/447 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BACH2 | c.1591G>A p.D531N | Missense Mutation (SNP) | VAF 106/668 reads (16%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BAHD1 | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 193/780 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- BLM | c.3175C>T p.P1059S | Missense Mutation (SNP) | VAF 52/272 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- BMP2 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 116/414 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- BRD8 | c.2137_2144del p.K713Hfs*10 (on ENST00000254900 / NM_139199.2; = p.K786Hfs*10 on NM_006696.4) | Frame Shift Del (DEL) | VAF 80/393 reads (20%) | called by mutect2, pindel, varscan2
- C17orf97 | c.214C>T p.P72S | Missense Mutation (SNP) | VAF 153/547 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- C6orf15 | c.773G>T p.G258V | Missense Mutation (SNP) | VAF 209/797 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- CA9 | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 173/657 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CAVIN2 | c.1274C>T p.S425F | Missense Mutation (SNP) | VAF 83/384 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- CAVIN2 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 196/696 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.298); called by muse, varscan2
- CCDC170 | c.1899G>A p.M633I | Missense Mutation (SNP) | VAF 106/445 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CCDC80 | c.2359C>T p.P787S | Missense Mutation (SNP) | VAF 85/492 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CCDC88B | c.2168G>A p.G723D | Missense Mutation (SNP) | VAF 163/656 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- CD163L1 | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 133/721 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CD1A | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 59/386 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CD48 | c.217A>T p.K73* | Nonsense Mutation (SNP) | VAF 123/434 reads (28%) | called by muse, mutect2, varscan2
- CD53 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 90/333 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); called by muse, mutect2, varscan2
- CDH11 | c.131A>T p.E44V | Missense Mutation (SNP) | VAF 178/700 reads (25%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- CEACAM3 | c.452G>A p.G151E | Missense Mutation (SNP) | VAF 72/578 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- CELF5 | c.396G>A p.R132= | Splice Region (SNP) | VAF 86/312 reads (28%) | called by muse, mutect2, varscan2
- CLCN1 | c.1346G>A p.W449* | Nonsense Mutation (SNP) | VAF 88/959 reads (9%) | called by muse, mutect2
- CLDN18 | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 83/312 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CLIC6 | c.1709G>A p.G570E (on ENST00000360731 / NM_001317009.2; = p.G552E on NM_053277.3) | Missense Mutation (SNP) | VAF 122/542 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLMN | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 84/345 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CNTNAP5 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 132/601 reads (22%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- COL25A1 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 102/445 reads (23%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- COL4A3 | c.3811G>A p.G1271R | Missense Mutation (SNP) | VAF 117/487 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL9A1 | c.1387G>A p.G463R | Missense Mutation (SNP) | VAF 81/332 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRTC1 | c.1795G>A p.E599K | Missense Mutation (SNP) | VAF 172/537 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- CRTC3 | c.1319C>T p.A440V | Missense Mutation (SNP) | VAF 122/490 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- CRYBG3 | c.1885A>T p.S629C | Missense Mutation (SNP) | VAF 123/371 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- CSMD1 | c.4916C>T p.S1639L (on ENST00000520002; = p.S1638L on NM_033225.6) | Missense Mutation (SNP) | VAF 102/359 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CSMD3 | c.8671T>C p.F2891L (on ENST00000297405 / NM_001363185.1; = p.F2722L on NM_052900.3) | Missense Mutation (SNP) | VAF 121/423 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CUBN | c.7396C>T p.P2466S | Missense Mutation (SNP) | VAF 96/414 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- CUL9 | c.345G>T p.M115I | Missense Mutation (SNP) | VAF 158/600 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- CYP21A2 | c.1124C>T p.S375F | Missense Mutation (SNP) | VAF 72/619 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DCTN4 | c.1144C>T p.P382S | Missense Mutation (SNP) | VAF 114/333 reads (34%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- DCTN4 | c.1143A>T p.E381D | Missense Mutation (SNP) | VAF 117/340 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DECR1 | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 85/569 reads (15%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DENND4A | c.5081C>T p.S1694F | Missense Mutation (SNP) | VAF 97/364 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- DENND4A | c.2716C>T p.L906F | Missense Mutation (SNP) | VAF 46/250 reads (18%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- DERL3 | c.434G>A p.G145D | Missense Mutation (SNP) | VAF 311/745 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DHRS4 | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 113/499 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- DICER1 | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 117/518 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- DLX1 | c.539G>A p.R180Q | Missense Mutation (SNP) | VAF 111/465 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH5 | c.5581C>T p.Q1861* | Nonsense Mutation (SNP) | VAF 138/431 reads (32%) | called by muse, mutect2, varscan2
- DNAH6 | c.7292G>T p.R2431M | Missense Mutation (SNP) | VAF 46/204 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH8 | c.9274G>A p.E3092K | Missense Mutation (SNP) | VAF 74/403 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- DOCK3 | c.2146G>A p.E716K | Missense Mutation (SNP) | VAF 99/504 reads (20%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- DOCK8 | c.532G>A p.G178S | Missense Mutation (SNP) | VAF 100/308 reads (32%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- DPP8 | c.197C>T p.A66V (on ENST00000341861 / NM_001320875.2; = p.A50V on NM_017743.6) | Missense Mutation (SNP) | VAF 175/723 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- DPYSL2 | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 101/420 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- DRD3 | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 73/520 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DSG1 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 47/223 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DSP | c.5131G>A p.E1711K | Missense Mutation (SNP) | VAF 156/560 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- DUSP10 | c.1370A>G p.E457G | Missense Mutation (SNP) | VAF 127/519 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DVL3 | c.1646C>T p.P549L | Missense Mutation (SNP) | VAF 136/792 reads (17%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.995); called by muse, varscan2
- E4F1 | c.1451T>C p.V484A | Missense Mutation (SNP) | VAF 153/667 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EFCAB13 | c.1261G>A p.D421N | Missense Mutation (SNP) | VAF 88/493 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- EFCAB3 | c.1121C>T p.T374I | Missense Mutation (SNP) | VAF 147/543 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- EFCAB8 | c.2637G>A p.W879* | Nonsense Mutation (SNP) | VAF 31/301 reads (10%) | called by muse, mutect2, varscan2
- EIF2B5 | c.590C>T p.S197F (on ENST00000647909; = p.S189F on NM_003907.3) | Missense Mutation (SNP) | VAF 100/648 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- ENPEP | c.77T>G p.V26G | Missense Mutation (SNP) | VAF 111/463 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ENPP4 | c.1022C>T p.S341F | Missense Mutation (SNP) | VAF 48/317 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- ERCC4 | c.2515C>T p.P839S | Missense Mutation (SNP) | VAF 156/623 reads (25%) | SIFT tolerated (0.76); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- FABP12 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 55/366 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- FADS6 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 122/459 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- FAM217A | c.571G>A p.G191R | Missense Mutation (SNP) | VAF 147/540 reads (27%) | SIFT tolerated (0.67); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- FAM83H | c.959T>G p.F320C | Missense Mutation (SNP) | VAF 195/730 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); called by mutect2, varscan2
- FASN | c.4643G>T p.C1548F | Missense Mutation (SNP) | VAF 174/770 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- FBXL18 | c.997C>T p.Q333* | Nonsense Mutation (SNP) | VAF 81/448 reads (18%) | called by muse, mutect2, varscan2
- FCRL5 | c.2791C>T p.Q931* | Nonsense Mutation (SNP) | VAF 35/295 reads (12%) | called by muse, mutect2, varscan2
- FEZ1 | c.590C>T p.S197F | Missense Mutation (SNP) | VAF 138/602 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- FILIP1 | c.2569C>T p.P857S | Missense Mutation (SNP) | VAF 118/512 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- FKBP6 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 43/400 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- FLG | c.11366G>A p.S3789N | Missense Mutation (SNP) | VAF 80/766 reads (10%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- FLI1 | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 152/684 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.017); called by muse, mutect2
- FLNB | c.5204C>T p.P1735L | Missense Mutation (SNP) | VAF 84/515 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- FRG2C | c.10G>A p.G4R | Missense Mutation (SNP) | VAF 73/559 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- G6PC2 | c.461G>T p.W154L | Missense Mutation (SNP) | VAF 88/432 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GAB3 | c.1280C>T p.P427L | Missense Mutation (SNP) | VAF 176/392 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- GABBR2 | c.2683C>T p.Q895* | Nonsense Mutation (SNP) | VAF 121/391 reads (31%) | called by muse, mutect2, varscan2
- GAPVD1 | c.1735C>T p.P579S | Missense Mutation (SNP) | VAF 56/207 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- GDPD4 | c.1745C>T p.T582I | Missense Mutation (SNP) | VAF 126/590 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- GGTLC2 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 136/452 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GNA12 | c.365C>T p.S122F | Missense Mutation (SNP) | VAF 45/377 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- GON4L | c.3118C>T p.P1040S | Missense Mutation (SNP) | VAF 87/631 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- GP6 | c.214G>A p.V72I | Missense Mutation (SNP) | VAF 125/858 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- GPBP1L1 | c.902C>T p.T301I | Missense Mutation (SNP) | VAF 93/336 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- GPN3 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 87/328 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- GPR63 | c.845G>A p.G282D | Missense Mutation (SNP) | VAF 145/627 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- GREB1L | c.1317A>T p.K439N | Missense Mutation (SNP) | VAF 126/389 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- GRIK3 | c.410G>A p.W137* | Nonsense Mutation (SNP) | VAF 95/659 reads (14%) | called by muse, mutect2, varscan2
- GRIN2D | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 111/352 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- GRM5 | c.3581C>T p.S1194F (on ENST00000305447 / NM_001143831.2; = p.S1162F on NM_000842.4) | Missense Mutation (SNP) | VAF 104/462 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- GSDMA | c.148G>A p.G50R | Missense Mutation (SNP) | VAF 103/346 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HCN3 | c.1750G>A p.G584S | Missense Mutation (SNP) | VAF 213/773 reads (28%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- HERC2 | c.1162G>T p.D388Y | Missense Mutation (SNP) | VAF 172/728 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HIPK2 | c.1331C>T p.P444L | Missense Mutation (SNP) | VAF 262/573 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HOXB2 | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 195/800 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HS6ST1 | c.782G>A p.G261D | Missense Mutation (SNP) | VAF 50/348 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSF2BP | c.458T>A p.F153Y | Missense Mutation (SNP) | VAF 93/472 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IFFO1 | c.1138G>A p.E380K (on ENST00000396840 / NM_001330324.2; = p.E383K on NM_080730.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 340/936 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.423); called by muse, varscan2
- IRAG1 | c.136C>T p.H46Y | Missense Mutation (SNP) | VAF 167/590 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IZUMO1R | c.318G>A p.W106* | Nonsense Mutation (SNP) | VAF 79/437 reads (18%) | called by muse, mutect2, varscan2
- JPH4 | c.1424C>T p.A475V | Missense Mutation (SNP) | VAF 238/916 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- KCNA7 | c.973C>T p.L325F | Missense Mutation (SNP) | VAF 99/643 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- KCNK10 | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 78/281 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KDM4D | c.1559C>T p.A520V | Missense Mutation (SNP) | VAF 65/354 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- KIF14 | c.3314A>G p.K1105R | Missense Mutation (SNP) | VAF 29/278 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KLF14 | c.101G>A p.G34D | Missense Mutation (SNP) | VAF 125/646 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- KMO | c.97C>T p.Q33* | Nonsense Mutation (SNP) | VAF 31/376 reads (8%) | called by muse, mutect2
- KRBOX4 | c.283C>T p.H95Y (on ENST00000344302 / NM_001129898.2; = p.H90Y on NM_017776.2) | Missense Mutation (SNP) | VAF 124/294 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KRTAP4-11 | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 135/415 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- KRTAP5-10 | c.214G>A p.G72R | Missense Mutation (SNP) | VAF 140/620 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, varscan2
- LAMA1 | c.956C>T p.S319F | Missense Mutation (SNP) | VAF 103/304 reads (34%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- LAMB3 | c.2636C>T p.S879F | Missense Mutation (SNP) | VAF 102/435 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- LAMC1 | c.1446del p.F482Lfs*68 | Frame Shift Del (DEL) | VAF 65/397 reads (16%) | called by mutect2, pindel, varscan2
- LEPR | c.3000A>C p.E1000D | Missense Mutation (SNP) | VAF 77/527 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LILRA6 | c.156C>G p.S52R | Missense Mutation (SNP) | VAF 77/314 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- LIPC | c.915G>A p.M305I | Missense Mutation (SNP) | VAF 142/545 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- LMNB2 | c.1666A>T p.T556S | Missense Mutation (SNP) | VAF 20/534 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.005); called by muse, mutect2
- LRRC36 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 70/354 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- LRRC3B | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 138/404 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRC69 | c.856G>A p.G286R | Missense Mutation (SNP) | VAF 57/484 reads (12%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRIQ3 | c.743A>T p.K248I | Missense Mutation (SNP) | VAF 67/262 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- MADD | c.3803C>T p.A1268V | Missense Mutation (SNP) | VAF 70/266 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- MALRD1 | c.3073T>C p.Y1025H | Missense Mutation (SNP) | VAF 53/318 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- MARVELD2 | c.151C>T p.L51F | Missense Mutation (SNP) | VAF 200/704 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MGAM | c.5231G>A p.G1744E | Missense Mutation (SNP) | VAF 384/823 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MIB2 | c.2827G>A p.E943K | Missense Mutation (SNP) | VAF 101/661 reads (15%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- MMRN2 | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 135/503 reads (27%) | SIFT tolerated (0.8); PolyPhen benign (0.003); called by muse, varscan2
- MOV10 | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 84/370 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- MOXD1 | c.1054C>T p.P352S | Missense Mutation (SNP) | VAF 118/504 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MPHOSPH9 | c.2516C>T p.S839F | Missense Mutation (SNP) | VAF 150/470 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MPP7 | c.278G>A p.R93K | Missense Mutation (SNP) | VAF 113/370 reads (31%) | SIFT tolerated (0.87); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MRPL49 | c.230-1G>A p.X77_splice | Splice Site (SNP) | VAF 89/360 reads (25%) | called by muse, mutect2, varscan2
- MUC16 | c.27764G>A p.G9255D | Missense Mutation (SNP) | VAF 26/529 reads (5%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.282); called by muse, mutect2
- MUC17 | c.2285C>T p.S762F | Missense Mutation (SNP) | VAF 155/804 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- MUC4 | c.7364C>T p.S2455F | Missense Mutation (SNP) | VAF 177/1758 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.496); called by muse, varscan2
- MYBL2 | c.1972C>T p.P658S | Missense Mutation (SNP) | VAF 106/393 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- MYO18B | c.4450G>A p.V1484I | Missense Mutation (SNP) | VAF 65/336 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- MYOM1 | c.1224T>G p.D408E | Missense Mutation (SNP) | VAF 111/421 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- NCOA6 | c.2900C>T p.S967L | Missense Mutation (SNP) | VAF 49/352 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NDRG3 | c.998C>T p.S333L (on ENST00000349004 / NM_032013.4; = p.S321L on NM_022477.4) | Missense Mutation (SNP) | VAF 74/479 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- NEB | c.8776G>A p.E2926K | Missense Mutation (SNP) | VAF 134/591 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- NFATC1 | c.1901C>T p.P634L | Missense Mutation (SNP) | VAF 84/266 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- NFATC3 | c.2552C>T p.S851F | Missense Mutation (SNP) | VAF 129/550 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- NLGN1 | c.1517G>A p.G506E | Missense Mutation (SNP) | VAF 92/540 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NLRP9 | c.815T>C p.L272P | Missense Mutation (SNP) | VAF 149/541 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NPFFR2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 42/295 reads (14%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NRBP2 | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 73/570 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- NUP210L | c.3761G>A p.R1254K | Missense Mutation (SNP) | VAF 116/491 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- NUTM1 | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 146/607 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- OGDHL | c.2989G>A p.D997N | Missense Mutation (SNP) | VAF 55/378 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- OGDHL | c.1381C>T p.H461Y | Missense Mutation (SNP) | VAF 82/553 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2L3 | c.891G>T p.M297I | Missense Mutation (SNP) | VAF 49/407 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR2M2 | c.584T>A p.F195Y | Missense Mutation (SNP) | VAF 92/448 reads (21%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- OR4B1 | c.614C>T p.S205F | Missense Mutation (SNP) | VAF 98/357 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- OR4K17 | c.804T>A p.D268E | Missense Mutation (SNP) | VAF 91/437 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- OR4K2 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 103/971 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- OR8B2 | c.902G>A p.R301K | Missense Mutation (SNP) | VAF 87/461 reads (19%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR8H2 | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 76/345 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- ORM1 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 73/514 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- OTOP1 | c.715G>T p.G239W | Missense Mutation (SNP) | VAF 23/220 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- OXER1 | c.481G>A p.G161R | Missense Mutation (SNP) | VAF 140/614 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- PCDHA7 | c.1163C>T p.S388F | Missense Mutation (SNP) | VAF 122/425 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- PCDHB6 | c.1684C>A p.P562T | Missense Mutation (SNP) | VAF 164/632 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, varscan2
- PCDHB6 | c.1685C>A p.P562Q | Missense Mutation (SNP) | VAF 169/636 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, varscan2
- PDGFC | c.595C>T p.L199F | Missense Mutation (SNP) | VAF 91/409 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- PERM1 | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 79/589 reads (13%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PGM5 | c.962_963delinsT p.N321Ifs*33 | Frame Shift Del (DEL) | VAF 100/882 reads (11%) | called by pindel, varscan2*
- PICK1 | c.575C>T p.S192F | Missense Mutation (SNP) | VAF 165/419 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- PIK3C2G | c.2209G>A p.G737S (on ENST00000676171; = p.G696S on NM_004570.5) | Missense Mutation (SNP) | VAF 102/693 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PIK3C2G | c.4078G>C p.V1360L (on ENST00000676171; = p.V1319L on NM_004570.5) | Missense Mutation (SNP) | VAF 49/346 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PIK3R4 | c.1958T>C p.V653A | Missense Mutation (SNP) | VAF 120/377 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- PKHD1L1 | c.10345G>A p.E3449K | Missense Mutation (SNP) | VAF 50/320 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- PKP2 | c.1165A>C p.K389Q | Missense Mutation (SNP) | VAF 102/445 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- PLA2R1 | c.219G>A p.W73* | Nonsense Mutation (SNP) | VAF 134/542 reads (25%) | called by muse, mutect2, varscan2
- PLCL2 | c.901C>T p.P301S (on ENST00000615277 / NM_001144382.2; = p.P175S on NM_015184.5) | Missense Mutation (SNP) | VAF 52/571 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.411); called by muse, mutect2
- PLPP1 | c.217C>T p.L73F | Missense Mutation (SNP) | VAF 66/218 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PNLIP | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 109/466 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- POU2AF1 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 160/697 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- PPP1R18 | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 252/1122 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- PRDM15 | c.3025G>T p.E1009* | Nonsense Mutation (SNP) | VAF 149/652 reads (23%) | called by muse, mutect2, varscan2
- PRPF3 | c.505C>T p.Q169* | Nonsense Mutation (SNP) | VAF 77/290 reads (27%) | called by muse, mutect2, varscan2
- PRR35 | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 275/1013 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PTF1A | c.157C>T p.L53F | Missense Mutation (SNP) | VAF 75/622 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTGIS | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 55/458 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRA | c.1814C>T p.A605V | Missense Mutation (SNP) | VAF 34/356 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- PTPRB | c.4186G>A p.E1396K | Missense Mutation (SNP) | VAF 133/502 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- RASSF10 | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 111/374 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- RBMXL3 | c.2494G>A p.G832S | Missense Mutation (SNP) | VAF 147/353 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- RBP3 | c.1508C>T p.P503L | Missense Mutation (SNP) | VAF 71/604 reads (12%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- RFX6 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 69/429 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- ROR1 | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 45/394 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- RPN1 | c.775G>A p.G259R | Missense Mutation (SNP) | VAF 85/579 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RTCA | c.174G>A p.M58I | Missense Mutation (SNP) | VAF 102/400 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RTEL1 | c.1939C>T p.P647S | Missense Mutation (SNP) | VAF 181/713 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RUNDC3B | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 67/350 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- RYR1 | c.2669G>A p.W890* | Nonsense Mutation (SNP) | VAF 43/398 reads (11%) | called by muse, mutect2, varscan2
- RYR2 | c.5532G>T p.Q1844H | Missense Mutation (SNP) | VAF 73/528 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- S100A7A | c.73G>A p.G25S | Missense Mutation (SNP) | VAF 74/542 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SAMD4B | c.1169C>T p.P390L | Missense Mutation (SNP) | VAF 87/553 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SCAPER | c.2128G>A p.E710K | Missense Mutation (SNP) | VAF 120/504 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SCIN | c.1198-1G>A p.X400_splice (on ENST00000297029 / NM_001112706.3; = p.X153_splice on NM_033128.3) | Splice Site (SNP) | VAF 28/249 reads (11%) | called by muse, mutect2, varscan2
- SCN1A | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 71/320 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- SCN7A | c.2383C>T p.L795F | Missense Mutation (SNP) | VAF 129/516 reads (25%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SEC24A | c.2149C>T p.P717S | Missense Mutation (SNP) | VAF 141/431 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- SEC24B | c.721C>T p.P241S | Missense Mutation (SNP) | VAF 61/427 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SEMA5B | c.2818C>T p.P940S | Missense Mutation (SNP) | VAF 100/612 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SEMA5B | c.155G>A p.R52K | Missense Mutation (SNP) | VAF 110/452 reads (24%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEMA6B | c.2453C>T p.P818L | Missense Mutation (SNP) | VAF 36/787 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.029); called by muse, mutect2
- SEMA6B | c.2452C>T p.P818S | Missense Mutation (SNP) | VAF 36/792 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2
- SESN1 | c.584C>T p.S195F (on ENST00000356644 / NM_001199933.1; = p.S254F on NM_014454.3) | Missense Mutation (SNP) | VAF 77/374 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SEZ6L2 | c.2158G>C p.D720H (on ENST00000308713 / NM_001114099.3; = p.D650H on NM_012410.4) | Missense Mutation (SNP) | VAF 140/649 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SIGLEC6 | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 147/564 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- SLC16A13 | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 156/613 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- SLC16A9 | c.691A>G p.S231G | Missense Mutation (SNP) | VAF 121/475 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC1A7 | c.962A>T p.K321M | Missense Mutation (SNP) | VAF 142/518 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- SLC22A16 | c.407G>A p.W136* | Nonsense Mutation (SNP) | VAF 96/544 reads (18%) | called by muse, mutect2, varscan2
- SLC25A37 | c.572C>T p.T191I | Missense Mutation (SNP) | VAF 129/507 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.752); called by muse, varscan2
- SLC26A1 | c.319T>C p.F107L | Missense Mutation (SNP) | VAF 85/584 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SLC40A1 | c.799G>A p.G267S | Missense Mutation (SNP) | VAF 84/384 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- SLC4A10 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 68/374 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SLC5A8 | c.838C>T p.L280F | Missense Mutation (SNP) | VAF 97/287 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC6A1 | c.1195T>C p.C399R | Missense Mutation (SNP) | VAF 105/545 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- SMC4 | c.772A>T p.I258F | Missense Mutation (SNP) | VAF 80/483 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SMIM35 | c.40C>T p.L14F | Missense Mutation (SNP) | VAF 95/464 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SNCAIP | c.2290C>T p.P764S | Missense Mutation (SNP) | VAF 130/415 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNTB1 | c.1027C>T p.P343S | Missense Mutation (SNP) | VAF 94/369 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); called by muse, varscan2
- SPATA17 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 44/358 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SPATA31A7 | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.545); called by mutect2, varscan2
- SPTBN1 | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 109/534 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPTBN2 | c.253C>T p.L85F | Missense Mutation (SNP) | VAF 150/763 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SSU72P8 | c.551G>A p.G184E | Missense Mutation (SNP) | VAF 122/761 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- SULT6B1 | c.133T>C p.F45L (on ENST00000535679 / NM_001367551.1; = p.F7L on NM_001032377.2) | Missense Mutation (SNP) | VAF 87/491 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- SV2B | c.1507G>A p.D503N | Missense Mutation (SNP) | VAF 53/255 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SVEP1 | c.7537G>A p.D2513N | Missense Mutation (SNP) | VAF 114/477 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYN3 | c.1568G>C p.G523A | Missense Mutation (SNP) | VAF 160/600 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- TAS1R1 | c.1883G>A p.R628K | Missense Mutation (SNP) | VAF 114/630 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- TCF23 | c.15G>T p.K5N | Missense Mutation (SNP) | VAF 102/467 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- TDRD15 | c.1045_1046insA p.L349Yfs*16 | Frame Shift Ins (INS) | VAF 63/370 reads (17%) | called by mutect2, pindel, varscan2
- TENM3 | c.7121G>A p.R2374K | Missense Mutation (SNP) | VAF 48/354 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- TG | c.1814C>T p.S605F | Missense Mutation (SNP) | VAF 70/531 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- TIE1 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 239/762 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TINAG | c.441G>A p.W147* | Nonsense Mutation (SNP) | VAF 94/452 reads (21%) | called by muse, mutect2
- TLE2 | c.1802G>A p.G601D | Missense Mutation (SNP) | VAF 184/557 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- TMPRSS11F | c.992G>A p.G331E | Missense Mutation (SNP) | VAF 115/428 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TOGARAM1 | c.2455C>T p.P819S | Missense Mutation (SNP) | VAF 120/567 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- TOGARAM2 | c.2870C>T p.S957F | Missense Mutation (SNP) | VAF 186/717 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- TOM1L1 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 72/310 reads (23%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.941); called by mutect2, varscan2
- TRAV17 | c.245G>A p.R82K | Missense Mutation (SNP) | VAF 115/481 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TRIL | c.1960G>A p.D654N | Missense Mutation (SNP) | VAF 86/574 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- TRIM38 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 200/566 reads (35%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- TRIM51 | c.1315T>A p.F439I | Missense Mutation (SNP) | VAF 59/269 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- TRIP10 | c.232C>T p.Q78* | Nonsense Mutation (SNP) | VAF 20/430 reads (5%) | called by muse, mutect2
- TSGA13 | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 90/467 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TSHZ2 | c.599A>T p.Q200L | Missense Mutation (SNP) | VAF 95/569 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TSNARE1 | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 85/619 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- TTBK1 | c.2168C>T p.A723V | Missense Mutation (SNP) | VAF 130/686 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); called by muse, varscan2
- TTBK1 | c.2765C>T p.P922L | Missense Mutation (SNP) | VAF 195/792 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TTC13 | c.877T>A p.F293I | Missense Mutation (SNP) | VAF 96/359 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- TTC3 | c.4819G>A p.E1607K | Missense Mutation (SNP) | VAF 62/253 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- TTC6 | c.2981T>C p.I994T | Missense Mutation (SNP) | VAF 59/303 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TTLL6 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 98/359 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- TTN | c.73970G>A p.G24657E (on ENST00000591111; = p.G17233E on NM_003319.4) | Missense Mutation (SNP) | VAF 133/597 reads (22%) | PolyPhen benign (0.439); called by muse, mutect2, varscan2
- TTN | c.59378G>A p.G19793E (on ENST00000591111; = p.G12369E on NM_003319.4) | Missense Mutation (SNP) | VAF 111/473 reads (23%) | PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- TTN | c.25434G>C p.Q8478H (on ENST00000591111; = p.Q7551H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 137/555 reads (25%) | PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TUBGCP3 | c.2029C>T p.L677F | Missense Mutation (SNP) | VAF 94/487 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TYW1 | c.1056A>C p.R352S | Missense Mutation (SNP) | VAF 68/638 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UBR4 | c.10981C>T p.P3661S | Missense Mutation (SNP) | VAF 69/482 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- UGGT2 | c.1418G>A p.G473E | Missense Mutation (SNP) | VAF 91/371 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UNC80 | c.2213G>C p.G738A | Missense Mutation (SNP) | VAF 156/724 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- VLDLR | c.2137G>A p.G713R | Missense Mutation (SNP) | VAF 95/382 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VLDLR | c.2138G>A p.G713E | Missense Mutation (SNP) | VAF 100/390 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VPS13C | c.10028C>T p.S3343F (on ENST00000644861 / NM_020821.3; = p.S3300F on NM_017684.5) | Missense Mutation (SNP) | VAF 83/361 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- WDR37 | c.7A>G p.T3A | Missense Mutation (SNP) | VAF 83/359 reads (23%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WFDC9 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 98/363 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- ZAN | c.8189del p.F2730Sfs*48 | Frame Shift Del (DEL) | VAF 88/982 reads (9%) | called by mutect2, pindel
- ZBTB40 | c.3641C>T p.A1214V | Missense Mutation (SNP) | VAF 71/522 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZC3H14 | c.419C>T p.T140I | Missense Mutation (SNP) | VAF 48/261 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ZC3H7A | c.2572C>T p.H858Y | Missense Mutation (SNP) | VAF 79/371 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZFPL1 | c.112C>T p.Q38* | Nonsense Mutation (SNP) | VAF 118/465 reads (25%) | called by muse, mutect2, varscan2
- ZMYND11 | c.437G>A p.R146K | Missense Mutation (SNP) | VAF 26/202 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF112 | c.1613C>T p.S538L (on ENST00000337401 / NM_001083335.2; = p.S532L on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 64/648 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.297); called by muse, mutect2
- ZNF263 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 133/661 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF433 | c.1231T>A p.Y411N | Missense Mutation (SNP) | VAF 135/536 reads (25%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- ZNF628 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 154/585 reads (26%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ZNF707 | c.832C>A p.H278N | Missense Mutation (SNP) | VAF 195/747 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ZNF75D | c.337C>T p.H113Y | Missense Mutation (SNP) | VAF 179/358 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- ZNF98 | c.862C>T p.H288Y | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); called by mutect2, varscan2
- ZSWIM6 | c.3004C>T p.L1002F | Missense Mutation (SNP) | VAF 119/402 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZWILCH | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 107/436 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCC9 | c.3340C>T p.L1114= | Silent (SNP) | VAF 114/592 reads (19%) | called by muse, mutect2, varscan2
- ABCG2 | c.1770C>T p.N590= | Silent (SNP) | VAF 55/438 reads (13%) | called by muse, mutect2, varscan2
- AC068580.4 | c.645C>T p.F215= | Silent (SNP) | VAF 134/441 reads (30%) | called by muse, mutect2, varscan2
- ACSBG1 | c.1239C>T p.L413= | Silent (SNP) | VAF 109/508 reads (21%) | catalogued as rs761346938, COSV99357321; called by muse, mutect2, varscan2
- ACSF2 | c.1053C>T p.T351= | Silent (SNP) | VAF 107/466 reads (23%) | called by muse, mutect2, varscan2
- ACTL8 | c.927G>A p.K309= | Silent (SNP) | VAF 150/615 reads (24%) | called by muse, mutect2, varscan2
- ACTL9 | c.936C>T p.P312= | Silent (SNP) | VAF 195/588 reads (33%) | catalogued as rs1180915280; called by muse, mutect2, varscan2
- ADA2 | c.216G>A p.K72= | Silent (SNP) | VAF 113/595 reads (19%) | catalogued as rs976511354; called by muse, mutect2, varscan2
- ADAM2 | c.2121G>A p.V707= | Silent (SNP) | VAF 43/408 reads (11%) | catalogued as COSV55867291; called by muse, mutect2
- ADAM7 | c.1674G>A p.K558= | Silent (SNP) | VAF 88/349 reads (25%) | catalogued as COSV51535074; called by muse, mutect2, varscan2
- ADAMTS2 | c.3210C>T p.F1070= | Silent (SNP) | VAF 97/310 reads (31%) | called by muse, mutect2, varscan2
- ADARB2 | c.1941C>T p.D647= | Silent (SNP) | VAF 195/681 reads (29%) | called by muse, mutect2, varscan2
- ADD2 | c.279C>T p.F93= | Silent (SNP) | VAF 126/561 reads (22%) | called by muse, mutect2, varscan2
- ADGRD2 | c.537C>T p.P179= | Silent (SNP) | VAF 203/607 reads (33%) | called by muse, mutect2, varscan2
- ADGRE3 | c.1677C>T p.F559= | Silent (SNP) | VAF 21/420 reads (5%) | called by muse, mutect2
- ANK2 | c.8442C>T p.L2814= | Silent (SNP) | VAF 115/415 reads (28%) | called by muse, mutect2, varscan2
- ANKK1 | c.984G>A p.L328= | Silent (SNP) | VAF 106/506 reads (21%) | catalogued as rs1387898626, COSV58274393; called by muse, mutect2, varscan2
- ANKRD24 | c.2256G>A p.G752= | Silent (SNP) | VAF 42/899 reads (5%) | called by muse, mutect2
- ANKS1A | c.3075C>T p.I1025= | Silent (SNP) | VAF 87/533 reads (16%) | catalogued as rs1225713443; called by muse, mutect2, varscan2
- ARHGAP23 | c.1674C>T p.D558= | Silent (SNP) | VAF 141/425 reads (33%) | called by muse, mutect2, varscan2
- ARPC4 | c.198C>T p.S66= | Silent (SNP) | VAF 96/485 reads (20%) | called by muse, mutect2, varscan2
- ASB10 | c.444C>T p.G148= (on ENST00000420175 / NM_001142459.2; = p.G133= on NM_080871.4) | Silent (SNP) | VAF 194/1172 reads (17%) | called by muse, mutect2, varscan2
- ASCC3 | c.3396C>T p.I1132= | Silent (SNP) | VAF 70/454 reads (15%) | called by muse, mutect2, varscan2
- ASPM | c.5841C>T p.L1947= | Silent (SNP) | VAF 60/565 reads (11%) | catalogued as COSV54126377; called by muse, mutect2, varscan2
- B4GALNT2 | c.405G>A p.P135= | Silent (SNP) | VAF 82/362 reads (23%) | catalogued as rs748550373, COSV55924983; called by muse, varscan2
- B4GALT2 | c.255C>T p.A85= | Silent (SNP) | VAF 182/684 reads (27%) | catalogued as rs1186815136; called by muse, mutect2, varscan2
- BCL6 | c.690C>T p.L230= | Silent (SNP) | VAF 158/722 reads (22%) | called by muse, mutect2, varscan2
- BTBD7 | c.906C>T p.I302= | Silent (SNP) | VAF 150/668 reads (22%) | called by muse, mutect2, varscan2
- C1orf141 | c.846C>T p.I282= | Silent (SNP) | VAF 56/337 reads (17%) | catalogued as rs371582957; called by muse, mutect2, varscan2
- CAPN1 | c.489C>T p.V163= | Silent (SNP) | VAF 130/584 reads (22%) | catalogued as rs1258484846; called by muse, mutect2, varscan2
- CAPN14 | c.831G>A p.R277= | Silent (SNP) | VAF 102/399 reads (26%) | called by muse, mutect2, varscan2
- CASS4 | c.1083G>A p.Q361= | Silent (SNP) | VAF 73/555 reads (13%) | catalogued as rs148219392; called by muse, mutect2, varscan2
- CAVIN2 | c.1275C>T p.S425= | Silent (SNP) | VAF 84/380 reads (22%) | catalogued as rs756586670; called by muse, mutect2, varscan2
- CCDC105 | c.558C>A p.P186= | Silent (SNP) | VAF 84/293 reads (29%) | called by muse, mutect2, varscan2
- CD177 | c.1017C>T p.S339= | Silent (SNP) | VAF 92/390 reads (24%) | catalogued as rs1304124340; called by muse, mutect2, varscan2
- CDH11 | c.1839C>T p.A613= | Silent (SNP) | VAF 34/755 reads (5%) | catalogued as COSV51757730; called by muse, mutect2
- CDK20 | c.612C>T p.F204= (on ENST00000325303 / NM_001039803.3; = p.F183= on NM_012119.4) | Silent (SNP) | VAF 124/398 reads (31%) | called by muse, mutect2, varscan2
- CDON | c.3252T>C p.F1084= | Silent (SNP) | VAF 87/364 reads (24%) | catalogued as rs1565500535; called by muse, mutect2, varscan2
- CES4A | c.981C>T p.I327= | Silent (SNP) | VAF 137/620 reads (22%) | catalogued as rs1269476900; called by muse, mutect2, varscan2
- CETP | c.396C>T p.F132= | Silent (SNP) | VAF 103/420 reads (25%) | catalogued as rs879848326, COSV52362206; called by muse, varscan2
- CHD2 | c.3936C>T p.T1312= | Silent (SNP) | VAF 102/463 reads (22%) | called by muse, mutect2, varscan2
- CHRNA2 | c.1185G>A p.L395= | Silent (SNP) | VAF 206/709 reads (29%) | called by muse, mutect2, varscan2
- CMPK1 | c.42C>T p.G14= | Silent (SNP) | VAF 117/410 reads (29%) | called by muse, mutect2, varscan2
- CNGB1 | c.2736C>T p.S912= | Silent (SNP) | VAF 125/492 reads (25%) | catalogued as rs781159411, COSV99212276, COSV99212397; called by muse, mutect2, varscan2
- CNR2 | c.318C>T p.F106= | Silent (SNP) | VAF 156/588 reads (27%) | catalogued as COSV65694710; called by muse, mutect2, varscan2
- COG5 | c.1831C>T p.L611= (on ENST00000347053 / NM_001379512.1; = p.L632= on NM_006348.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 95/513 reads (19%) | catalogued as rs898773131; called by muse, mutect2, varscan2
- CPED1 | c.2652C>T p.I884= | Silent (SNP) | VAF 218/481 reads (45%) | catalogued as rs1182941153, COSV60007071; called by muse, mutect2, varscan2
- CR1 | c.2454C>T p.G818= | Silent (SNP) | VAF 31/326 reads (10%) | called by muse, varscan2
- CRB1 | c.1068G>A p.E356= | Silent (SNP) | VAF 82/601 reads (14%) | called by muse, mutect2, varscan2
- CSNKA2IP | c.1551G>A p.V517= | Silent (SNP) | VAF 70/387 reads (18%) | called by muse, mutect2, varscan2
- CTTNBP2 | c.2433G>A p.Q811= | Silent (SNP) | VAF 58/658 reads (9%) | called by muse, mutect2
- CYP1B1 | c.1584C>T p.L528= | Silent (SNP) | VAF 107/448 reads (24%) | catalogued as COSV52227529; called by muse, mutect2, varscan2
- CYP2W1 | c.1140C>T p.P380= | Silent (SNP) | VAF 78/446 reads (17%) | catalogued as rs763125088; called by muse, mutect2, varscan2
- DBF4B | c.264C>T p.I88= | Silent (SNP) | VAF 96/347 reads (28%) | catalogued as rs769717083, COSV59261914; called by muse, mutect2, varscan2
- DCTN2 | c.402C>T p.T134= (on ENST00000548249 / NM_001261413.2; = p.T139= on NM_006400.4) | Silent (SNP) | VAF 105/431 reads (24%) | called by muse, mutect2, varscan2
- DDN | c.939C>T p.V313= | Silent (SNP) | VAF 205/602 reads (34%) | called by muse, mutect2, varscan2
- DDX60L | c.4770C>T p.I1590= | Silent (SNP) | VAF 37/260 reads (14%) | catalogued as rs1326178647, COSV52716273; called by muse, mutect2, varscan2
- DLEC1 | c.891G>A p.R297= | Silent (SNP) | VAF 62/363 reads (17%) | called by muse, mutect2, varscan2
- DNTT | c.39G>A p.K13= | Silent (SNP) | VAF 126/451 reads (28%) | catalogued as COSV64523394; called by muse, mutect2, varscan2
- DOCK8 | c.1353C>T p.S451= | Silent (SNP) | VAF 132/516 reads (26%) | called by muse, mutect2, varscan2
- DYSF | c.2793C>T p.F931= | Silent (SNP) | VAF 69/382 reads (18%) | catalogued as rs146006518; ClinVar: likely benign; called by muse, mutect2, varscan2
- DZANK1 | c.990C>T p.P330= (on ENST00000262547 / NM_001099407.1; = p.P131= on NM_018152.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/499 reads (6%) | catalogued as rs372956678; called by muse, mutect2
- E4F1 | c.2067C>T p.I689= | Silent (SNP) | VAF 122/643 reads (19%) | catalogued as rs779587447, COSV57037385; called by muse, varscan2
- EFCAB8 | c.2046C>A p.P682= | Silent (SNP) | VAF 92/336 reads (27%) | called by muse, mutect2
- EFTUD2 | c.1476C>G p.A492= | Silent (SNP) | VAF 161/565 reads (28%) | catalogued as rs776284894; called by muse, mutect2, varscan2
- EIF2B5 | c.591C>T p.S197= (on ENST00000647909; = p.S189= on NM_003907.3) | Silent (SNP) | VAF 101/653 reads (15%) | called by muse, mutect2, varscan2
- ELAVL4 | c.915C>T p.S305= | Silent (SNP) | VAF 60/389 reads (15%) | called by muse, mutect2, varscan2
- EML6 | c.1362C>T p.I454= | Silent (SNP) | VAF 139/591 reads (24%) | catalogued as rs771233110, COSV100728393; called by muse, mutect2, varscan2
- ENG | c.1077C>T p.I359= | Silent (SNP) | VAF 183/519 reads (35%) | catalogued as COSV61226388; called by muse, mutect2, varscan2
- ENKD1 | c.876C>T p.L292= | Silent (SNP) | VAF 137/637 reads (22%) | catalogued as rs1371626190; called by muse, mutect2, varscan2
- EPAS1 | c.1878C>T p.T626= | Silent (SNP) | VAF 193/725 reads (27%) | called by muse, mutect2, varscan2
- EPHA3 | c.2001C>T p.F667= | Silent (SNP) | VAF 55/463 reads (12%) | catalogued as rs1175020790, COSV60722074; called by muse, mutect2, varscan2
- EPHA3 | c.2724G>A p.V908= | Silent (SNP) | VAF 74/466 reads (16%) | catalogued as rs1361552040; called by muse, mutect2, varscan2
- EPHA6 | c.3099C>T p.A1033= | Silent (SNP) | VAF 73/449 reads (16%) | called by muse, mutect2, varscan2
- EPHB6 | c.1803C>T p.I601= | Silent (SNP) | VAF 181/871 reads (21%) | catalogued as rs538727287; called by muse, mutect2, varscan2
- ERI2 | c.1110T>A p.A370= | Silent (SNP) | VAF 142/601 reads (24%) | called by muse, mutect2, varscan2
- ERVV-2 | c.1245G>A p.A415= | Silent (SNP) | VAF 66/574 reads (11%) | catalogued as rs1387634056; called by muse, mutect2, varscan2
- EVPL | c.2184C>T p.T728= | Silent (SNP) | VAF 168/719 reads (23%) | catalogued as rs765185512; called by muse, mutect2, varscan2
- FAM181A | c.429G>T p.L143= | Silent (SNP) | VAF 164/687 reads (24%) | called by muse, mutect2, varscan2
- FAM20B | c.918C>T p.I306= | Silent (SNP) | VAF 87/309 reads (28%) | catalogued as COSV99762542; called by muse, mutect2, varscan2
- FAM71F2 | c.237C>T p.L79= | Silent (SNP) | VAF 86/942 reads (9%) | catalogued as rs374923915; called by muse, mutect2
- FAM76A | c.613C>T p.L205= | Silent (SNP) | VAF 61/394 reads (15%) | called by muse, mutect2, varscan2
- FAM83F | c.1290G>A p.G430= | Silent (SNP) | VAF 295/619 reads (48%) | catalogued as rs1304428669, COSV100328938; called by muse, mutect2, varscan2
- FANCD2 | c.2097C>T p.L699= | Silent (SNP) | VAF 122/590 reads (21%) | catalogued as COSV55032508; called by muse, varscan2
- FAT4 | c.6798A>T p.V2266= | Silent (SNP) | VAF 87/322 reads (27%) | called by muse, mutect2, varscan2
- FBXW9 | c.1068C>T p.A356= (on ENST00000587955; = p.A336= on NM_032301.3) | Silent (SNP) | VAF 142/493 reads (29%) | called by muse, mutect2, varscan2
- FEM1C | c.375C>T p.F125= | Silent (SNP) | VAF 177/531 reads (33%) | catalogued as rs201126135; called by muse, mutect2, varscan2
- FKBP8 | c.783C>T p.F261= (on ENST00000222308 / NM_001308373.2; = p.F262= on NM_012181.5) | Silent (SNP) | VAF 94/317 reads (30%) | catalogued as rs907796351, COSV99724184; called by muse, mutect2, varscan2
- FMNL2 | c.1045C>T p.L349= | Silent (SNP) | VAF 75/387 reads (19%) | called by muse, mutect2, varscan2
- FRMD4A | c.1032G>A p.T344= | Silent (SNP) | VAF 80/504 reads (16%) | catalogued as rs374188244, COSV52715388; called by muse, mutect2, varscan2
- FRMPD1 | c.1884C>T p.F628= | Silent (SNP) | VAF 138/412 reads (33%) | called by muse, mutect2, varscan2
- FSHR | c.219G>A p.E73= | Silent (SNP) | VAF 80/323 reads (25%) | catalogued as rs377397067, COSV58624679; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FZD10 | c.1494C>T p.I498= | Silent (SNP) | VAF 160/502 reads (32%) | catalogued as COSV57473551; called by muse, mutect2, varscan2
- GABRA4 | c.858C>T p.P286= | Silent (SNP) | VAF 56/286 reads (20%) | catalogued as rs773617570; called by muse, mutect2, varscan2
- GABRP | c.648C>T p.F216= | Silent (SNP) | VAF 97/334 reads (29%) | catalogued as COSV54663344; called by muse, mutect2, varscan2
- GIMAP2 | c.951C>T p.P317= | Silent (SNP) | VAF 83/492 reads (17%) | catalogued as rs752117718; called by muse, mutect2, varscan2
- GINM1 | c.375C>T p.S125= | Silent (SNP) | VAF 120/450 reads (27%) | catalogued as rs749425002, COSV100805341; called by muse, varscan2
- GOLGA6L9 | c.138G>A p.R46= | Silent (SNP) | VAF 80/376 reads (21%) | called by muse, mutect2, varscan2
- GPANK1 | c.768C>T p.S256= | Silent (SNP) | VAF 174/1009 reads (17%) | catalogued as rs755257896; called by muse, mutect2, varscan2
- GPR62 | c.168C>T p.V56= | Silent (SNP) | VAF 198/725 reads (27%) | catalogued as rs572679692; called by muse, mutect2, varscan2
- GTSF1L | c.102C>A p.P34= | Silent (SNP) | VAF 84/561 reads (15%) | called by muse, mutect2, varscan2
- HAO2 | c.9G>A p.L3= | Silent (SNP) | VAF 58/310 reads (19%) | called by muse, mutect2, varscan2
- HARS1 | c.84C>T p.A28= | Silent (SNP) | VAF 77/272 reads (28%) | called by muse, mutect2, varscan2
- HCFC1 | c.5697C>T p.I1899= | Silent (SNP) | VAF 103/238 reads (43%) | called by muse, mutect2, varscan2
- HHIP | c.1221C>T p.S407= | Silent (SNP) | VAF 124/452 reads (27%) | catalogued as rs200328457; called by muse, varscan2
- HIBADH | c.729C>T p.I243= | Silent (SNP) | VAF 61/362 reads (17%) | catalogued as COSV55315881; called by muse, mutect2, varscan2
- HID1 | c.345G>A p.R115= | Silent (SNP) | VAF 154/680 reads (23%) | called by muse, mutect2, varscan2
- HRNR | c.8552G>A p.*2851= | Silent (SNP) | VAF 65/242 reads (27%) | catalogued as rs148501012, COSV64263729; called by muse, varscan2
- HUS1 | c.825C>T p.F275= | Silent (SNP) | VAF 43/330 reads (13%) | catalogued as COSV99034095; called by muse, mutect2, varscan2
- HYDIN | c.10854C>T p.I3618= | Silent (SNP) | VAF 3/14 reads (21%) | called by mutect2, varscan2
- HYDIN | c.6843G>A p.K2281= | Silent (SNP) | VAF 61/516 reads (12%) | catalogued as COSV99992436; called by muse, mutect2, varscan2
- IFFO1 | c.1137G>A p.S379= (on ENST00000396840 / NM_001330324.2; = p.S382= on NM_080730.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 373/1007 reads (37%) | catalogued as rs367764312; called by muse, mutect2, varscan2
- IGFN1 | c.1650G>A p.V550= (on ENST00000295591 / NM_001367841.1; = p.V3007= on NM_001164586.2) | Silent (SNP) | VAF 49/413 reads (12%) | catalogued as COSV55177646; called by muse, mutect2, varscan2
- IGHV1-69 | c.348G>A p.A116= | Silent (SNP) | VAF 85/203 reads (42%) | catalogued as rs782645516; called by muse, mutect2, varscan2
- IGKV1D-16 | c.36C>T p.L12= | Silent (SNP) | VAF 114/554 reads (21%) | catalogued as rs1353537280; called by muse, mutect2, varscan2
- IL36B | c.33C>T p.S11= | Silent (SNP) | VAF 109/437 reads (25%) | catalogued as rs777632544, COSV52084790, COSV52088843; called by muse, mutect2, varscan2
- IQSEC2 | c.2377C>T p.L793= (on ENST00000642864 / NM_001111125.3; = p.L588= on NM_015075.2) | Silent (SNP) | VAF 205/397 reads (52%) | called by muse, mutect2, varscan2
- IQSEC2 | c.246C>T p.S82= | Silent (SNP) | VAF 197/407 reads (48%) | called by muse, mutect2, varscan2
- IRF2BP1 | c.1545C>T p.F515= | Silent (SNP) | VAF 90/657 reads (14%) | catalogued as COSV56193291; called by muse, mutect2, varscan2
- ITGAL | c.396C>T p.F132= | Silent (SNP) | VAF 122/562 reads (22%) | called by muse, mutect2, varscan2
- ITGAX | c.711C>T p.H237= | Silent (SNP) | VAF 95/372 reads (26%) | called by muse, mutect2, varscan2
- JAK1 | c.1194C>T p.S398= | Silent (SNP) | VAF 87/355 reads (25%) | called by muse, mutect2, varscan2
- JPH1 | c.642G>A p.R214= | Silent (SNP) | VAF 155/565 reads (27%) | called by muse, mutect2, varscan2
- KALRN | c.4110G>A p.Q1370= | Silent (SNP) | VAF 81/428 reads (19%) | catalogued as COSV53777780; called by muse, mutect2, varscan2
- KBTBD12 | c.165T>C p.Y55= | Silent (SNP) | VAF 100/475 reads (21%) | called by muse, mutect2, varscan2
- KCNG1 | c.912C>T p.I304= | Silent (SNP) | VAF 143/589 reads (24%) | catalogued as rs17791052; called by muse, mutect2, varscan2
- KIAA1549 | c.2733G>A p.E911= | Silent (SNP) | VAF 108/978 reads (11%) | catalogued as rs373323741, COSV104386723; called by muse, mutect2, varscan2
- KIAA1755 | c.1389C>T p.S463= | Silent (SNP) | VAF 108/699 reads (15%) | catalogued as COSV99641997; called by muse, mutect2, varscan2
- KIF13B | c.4446C>T p.P1482= | Silent (SNP) | VAF 52/412 reads (13%) | called by muse, mutect2, varscan2
- KIR2DL3 | c.462C>T p.S154= | Silent (SNP) | VAF 88/395 reads (22%) | called by muse, mutect2, varscan2
- KLC4 | c.1362G>A p.K454= | Silent (SNP) | VAF 117/473 reads (25%) | called by muse, mutect2, varscan2
- KMT2D | c.2601C>T p.P867= | Silent (SNP) | VAF 185/682 reads (27%) | called by muse, mutect2, varscan2
- KPNA7 | c.153G>A p.T51= | Silent (SNP) | VAF 70/603 reads (12%) | catalogued as rs1255848661, COSV59398487; called by muse, mutect2, varscan2
- KRT17 | c.60G>A p.L20= | Silent (SNP) | VAF 144/512 reads (28%) | catalogued as rs1016619635, COSV60860079; called by muse, mutect2, varscan2
- KRT27 | c.348C>T p.I116= | Silent (SNP) | VAF 86/303 reads (28%) | called by muse, mutect2, varscan2
218 further variants in this file (0 protein-altering or splice-affecting, 181 silent, 37 other) are not listed here.
